Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4449, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4449-01A (Primary Tumor).

■

Diagnosis/diagnoses:

1.: Tumor-free lymph nodes.

2.: Total gastrectomy preparation with the inclusion of a moderately differentiated mucigenous adenocarcinoma (intestinal type) in the prepyloric antrum of the stomach, with a maximum diameter of 3 cm, with infiltration of the perigastric fatty tissue and a further moderately differentiated adenocarcinoma (intestinal type), likewise in the antrum, measuring 1.5 cm in diameter, with circumscribed infiltration of the tunica submucosa. Six regional lymph node metastases in the region of the greater curvature. Tumor-free esophageal resection margin covered with characteristic squamous epithelium and tumor-free duodenal resection margin. Tumor-free omentum.

Tumor stage: pT2b (2) pN1 (6/42) pMX; ■

Source: NCI Genomic Data Commons file 87789031-3192-424b-b84a-f5ed6b6ba33b (TCGA-CG-4449.05CD8A06-A4A6-4975-AF7B-638C92CDE38D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).